Surgical pathology report (de-identified scan), TCGA case TCGA-EB-A6QZ, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Asterand, specimen TCGA-EB-A6QZ-01A (Primary Tumor).

Patient ID.

Surgical Date:

Gross Description: There is a skin flap with a black spot up to 2 x 1.6 cm in its size. Tumor gross thickness is up to 4 mm. Resection margins are of the normal structure.

Microscopic Description: Malignant melanoma of the skin, pigmented. Tumor Breslow thickness is 3 mm.

Diagnosis Details: Tumor Features: Pigmented, Tumor Extent: Tumor 2.01x4mm with or without ulceration, Venous Invasion: Absent, Margins: Absent, Treatment Effect:

Comments:

Formatted Path Reports: SKIN TISSUE CHECKLIST

Specimen type: Excision of skin lesion

Tumor site: Skin, hip

Tumor size: 1.6 x 0.3 x 2 cm

Tumor features: Pigmented

Satellite nodules: Not specified

Histologic type: Malignant melanoma

Histologic grade: Not specified

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Absent

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Tumor Breslow thickness is 3 mm.

Comments: None

ICD-O-3

Melanoma, malignant NOS
8720/3

C&F

Site Skin NOS C44.9

path

Skin hip C44.7

7/15/13

Primary Malignancy History		✓

Source: NCI Genomic Data Commons file cbdf2e84-cfa1-426b-aa79-43e4a37dfcde (TCGA-EB-A6QZ.95BB2C71-EB77-4A68-A4FB-1067A845CBAF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).